Somatic mutation profile of tumor specimen TCGA-43-5668-01A (aliquot TCGA-43-5668-01A-01D-1632-08) from TCGA case TCGA-43-5668, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 78.4 years (28,635 days).
Specimen TCGA-43-5668-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 22e6d884-4d40-40a0-a333-c000abf48eed.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-43-5668-10A (Blood Derived Normal), aliquot TCGA-43-5668-10A-01D-1632-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5f0e2f26-1ba2-4b11-834c-be790ded0cd0

The open-access MAF lists 718 somatic variants for this specimen: 539 protein-altering or splice-affecting, 159 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 447, Silent 159, Nonsense Mutation 39, Splice Site 22, Frame Shift Del 16, Intron 11, Splice Region 6, Frame Shift Ins 6, RNA 5, 3'UTR 2, In Frame Del 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA1 | c.5153-1G>A p.X1718_splice | Splice Site (SNP) | VAF 10/31 reads (32%) | catalogued as rs80358137, CS000586, CS961493, CS993672, COSV58784299; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ENPP1 | c.795+1G>A p.X265_splice | Splice Site (SNP) | VAF 7/24 reads (29%) | catalogued as rs753851892, CS120220, COSV62930278; ClinVar: pathogenic; called by muse, mutect2, varscan2
- JUN | c.334G>C p.E112Q | Missense Mutation (SNP) | VAF 21/94 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs1184098204, COSV64664188, COSV64664376; called by muse, mutect2, varscan2
- MED12 | c.3670C>G p.L1224V | Missense Mutation (SNP) | VAF 8/22 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1057519912, COSV61329632, COSV61332429; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SALL1 | c.826C>T p.R276* | Nonsense Mutation (SNP) | VAF 25/110 reads (23%) | catalogued as rs104894537, CM991123, COSV51753567; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>T p.R273L | Missense Mutation (SNP) | VAF 8/26 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- AASS | c.1894T>C p.Y632H | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV62788996; called by muse, mutect2
- ABCA13 | c.13544T>C p.V4515A | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.149); catalogued as COSV68943692; called by muse, mutect2
- ABCB1 | c.2279T>C p.L760P | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55945495; called by muse, mutect2, varscan2
- ABCB1 | c.2020G>T p.G674* | Nonsense Mutation (SNP) | VAF 15/89 reads (17%) | catalogued as COSV55945506; called by muse, mutect2, varscan2
- ABCB4 | c.2390G>T p.R797I | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); catalogued as COSV55932223; called by muse, mutect2, varscan2
- ACBD6 | c.663G>T p.Q221H | Missense Mutation (SNP) | VAF 19/169 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV62571738; called by muse, mutect2, varscan2
- ACOX3 | c.2002G>T p.G668C | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.781); catalogued as COSV62710882; called by muse, mutect2, varscan2
- ACVR2A | c.1120G>T p.A374S | Missense Mutation (SNP) | VAF 39/178 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV54019344; called by muse, mutect2, varscan2
- ADGRA3 | c.1147A>T p.S383C | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV51560441; called by muse, mutect2, varscan2
- ADGRL4 | c.832T>A p.Y278N | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV66059507; called by muse, mutect2
- ADH7 | c.577G>T p.G193C | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1248901584, COSV52919689; called by muse, mutect2, varscan2
- AGAP2 | c.1513C>G p.R505G (on ENST00000547588 / NM_001122772.2; = p.R169G on NM_014770.4) | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.422); catalogued as COSV57726893; called by muse, mutect2, varscan2
- ALDH4A1 | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.697); catalogued as rs942019101, COSV51890237; called by muse, mutect2, varscan2
- ALG1 | c.649A>C p.K217Q | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as COSV52156304; called by muse, mutect2, varscan2
- ALMS1 | c.3122A>T p.E1041V | Missense Mutation (SNP) | VAF 45/133 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV52503313; called by muse, mutect2, varscan2
- ALMS1 | c.11224G>T p.E3742* | Nonsense Mutation (SNP) | VAF 14/56 reads (25%) | catalogued as COSV52503330; called by muse, mutect2, varscan2
- ALPK3 | c.1402C>G p.H468D | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV51930076; called by muse, varscan2
- AMER1 | c.278G>T p.S93I | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV57655277; called by muse, mutect2, varscan2
- AMER3 | c.1924C>A p.Q642K | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.762); catalogued as COSV100366075; called by muse, mutect2
- ANKK1 | c.718G>T p.A240S | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.222); catalogued as COSV58270416; called by muse, mutect2
- ANKS3 | c.1801C>T p.P601S | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.034); catalogued as COSV58507321; called by muse, mutect2, varscan2
- ANLN | c.892A>G p.K298E | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.11); catalogued as COSV56074088; called by muse, mutect2, varscan2
- AOC1 | c.1121T>A p.V374D | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as COSV100710775, COSV62866959; called by muse, mutect2
- API5 | c.811G>C p.G271R | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.579); catalogued as rs778230801, COSV66632495; called by muse, mutect2, varscan2
- AQP5 | c.22G>T p.V8L | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV52229047, COSV52230618; called by muse, mutect2, varscan2
- ARHGAP29 | c.912G>T p.R304S | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1008764547, COSV53108575; called by muse, mutect2
- ARID2 | c.1561G>T p.E521* | Nonsense Mutation (SNP) | VAF 63/122 reads (52%) | catalogued as COSV57596524, COSV57615677; called by muse, mutect2, varscan2
- ARMC4 | c.2341G>A p.G781R | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59456614; called by muse, mutect2, varscan2
- ASB17 | c.530del p.N177Tfs*7 | Frame Shift Del (DEL) | VAF 8/79 reads (10%) | catalogued as rs749460467; called by mutect2, pindel
- ASB4 | c.423C>A p.H141Q | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV57507370; called by muse, mutect2, varscan2
- ASIC1 | c.1051G>A p.D351N | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.337); catalogued as COSV57316223; called by muse, mutect2
- ASTN1 | c.3514G>T p.E1172* | Nonsense Mutation (SNP) | VAF 7/51 reads (14%) | catalogued as COSV62491422; called by muse, mutect2, varscan2
- ASXL3 | c.4429C>T p.H1477Y | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV52457989; called by muse, mutect2, varscan2
- ATG4C | c.1346G>C p.R449T | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.66); catalogued as COSV58603833, COSV58606729; called by muse, mutect2, varscan2
- ATP10D | c.691-1G>T p.X231_splice | Splice Site (SNP) | VAF 7/37 reads (19%) | catalogued as COSV56704040; called by muse, mutect2
- ATP10D | c.691G>T p.D231Y | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV56704052; called by muse, mutect2, varscan2
- ATP6V0A1 | c.1105A>T p.K369* | Nonsense Mutation (SNP) | VAF 32/144 reads (22%) | catalogued as COSV52870899; called by muse, mutect2, varscan2
- ATP6V0A2 | c.604G>A p.V202M | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.311); catalogued as rs776619252, COSV57747784; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP8A2 | c.1785T>A p.D595E | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV54938032; called by muse, mutect2
- B3GALT2 | c.1075C>G p.P359A | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.251); catalogued as COSV66463823; called by muse, mutect2, varscan2
- BANK1 | c.422A>C p.Q141P | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59838616; called by muse, mutect2
- BAZ2B | c.143G>A p.C48Y | Missense Mutation (SNP) | VAF 40/157 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs1346604912, COSV58596132; called by muse, mutect2, varscan2
- BBS2 | c.1121G>A p.R374Q | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.06); catalogued as rs371765731; called by muse, mutect2, varscan2
- BPIFB1 | c.1376C>A p.A459D | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV53605193; called by muse, mutect2, varscan2
- BRINP2 | c.1578G>T p.E526D | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as COSV64175517; called by muse, mutect2, varscan2
- BRINP2 | c.1852G>C p.V618L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV64175526; called by muse, mutect2, varscan2
- C1QTNF6 | c.232G>T p.G78C | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.864); catalogued as COSV55395757, COSV55396600; called by muse, mutect2, varscan2
- C1orf198 | c.664G>T p.E222* | Nonsense Mutation (SNP) | VAF 10/84 reads (12%) | catalogued as COSV64174517; called by muse, mutect2, varscan2
- C6 | c.869G>T p.S290I | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.316); catalogued as COSV54705361; called by muse, mutect2, varscan2
- C8A | c.1604-1G>T p.X535_splice | Splice Site (SNP) | VAF 13/38 reads (34%) | catalogued as COSV63483012, COSV63483143; called by muse, mutect2, varscan2
- C8A | c.1604G>T p.G535V | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.139); catalogued as COSV63483146; called by muse, mutect2, varscan2
- C9orf24 | c.321C>A p.Y107* | Nonsense Mutation (SNP) | VAF 43/111 reads (39%) | catalogued as COSV52623798; called by muse, mutect2, varscan2
- CAPN6 | c.1487A>T p.E496V | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV60693943; called by muse, mutect2, varscan2
- CAPN6 | c.1156C>A p.Q386K | Missense Mutation (SNP) | VAF 79/142 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV60693952; called by muse, mutect2, varscan2
- CASP8 | c.326C>G p.S109* (on ENST00000432109 / NM_033355.3; = p.S141* on NM_001228.4) | Nonsense Mutation (SNP) | VAF 16/56 reads (29%) | catalogued as COSV51845577, COSV51845735; called by muse, mutect2, varscan2
- CCDC15 | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.28); catalogued as COSV61080363; called by muse, mutect2, varscan2
- CCHCR1 | c.2290G>T p.V764F | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.17); catalogued as COSV52535098; called by muse, mutect2, varscan2
- CCNB1 | c.588A>C p.E196D | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV56509146; called by muse, mutect2, varscan2
- CCR4 | c.383T>A p.V128D | Missense Mutation (SNP) | VAF 81/184 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as COSV58381481; called by muse, mutect2, varscan2
- CD109 | c.2048G>T p.S683I | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV54645591; called by muse, mutect2, varscan2
- CD163 | c.1165G>T p.E389* | Nonsense Mutation (SNP) | VAF 17/53 reads (32%) | catalogued as COSV100775884, COSV63129661; called by muse, mutect2, varscan2
- CD180 | c.1342C>T p.Q448* | Nonsense Mutation (SNP) | VAF 33/75 reads (44%) | catalogued as COSV56516934; called by muse, mutect2, varscan2
- CD37 | c.662C>A p.A221E | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT tolerated (0.5); PolyPhen benign (0.017); catalogued as COSV60543532; called by muse, mutect2, varscan2
- CDC42BPB | c.3447C>T p.L1149= | Splice Region (SNP) | VAF 20/48 reads (42%) | catalogued as COSV63473946; called by muse, mutect2, varscan2
- CDH10 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV52570770, COSV52593647; called by muse, mutect2, varscan2
- CDH8 | c.667+1G>C p.X223_splice | Splice Site (SNP) | VAF 18/76 reads (24%) | catalogued as COSV54849922; called by muse, mutect2, varscan2
- CDK13 | c.2948C>G p.P983R | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51696565; called by muse, mutect2, varscan2
- CELA2A | c.132C>G p.V44= | Splice Region (SNP) | VAF 10/58 reads (17%) | catalogued as COSV62747224; called by muse, mutect2, varscan2
- CELSR3 | c.9751G>C p.A3251P | Missense Mutation (SNP) | VAF 51/116 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV50840409; called by muse, mutect2, varscan2
- CENPB | c.304G>T p.E102* | Nonsense Mutation (SNP) | VAF 27/73 reads (37%) | catalogued as COSV60144466; called by muse, mutect2, varscan2
- CEP57L1 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100425988, COSV61244206; called by muse, mutect2, varscan2
- CFAP91 | c.749G>T p.W250L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56342213; called by muse, mutect2
- CGA | c.338A>T p.Y113F | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as COSV63644125; called by mutect2, varscan2
- CHD4 | c.2241G>C p.Q747H (on ENST00000357008 / NM_001363606.2; = p.Q760H on NM_001273.5) | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58895316; called by muse, mutect2, varscan2
- CHL1 | c.2696G>T p.G899V (on ENST00000397491 / NM_001253387.1; = p.G915V on NM_006614.4) | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56587040, COSV56601337; called by muse, mutect2, varscan2
- CHRNG | c.359G>A p.G120D | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67315267; called by muse, mutect2, varscan2
- CHST1 | c.872C>A p.P291Q | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.265); catalogued as COSV57321916, COSV57325297; called by muse, mutect2, varscan2
- CHST11 | c.992A>G p.Y331C | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV57984054; called by muse, mutect2, varscan2
- CLHC1 | c.615G>C p.Q205H | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.887); catalogued as COSV63427057; called by muse, mutect2, varscan2
- CLMN | c.601A>G p.T201A | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.872); catalogued as COSV54179234; called by muse, mutect2, varscan2
- CNTN3 | c.2925G>T p.K975N | Missense Mutation (SNP) | VAF 22/202 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV55163773; called by muse, mutect2, varscan2
- COL12A1 | c.1717G>C p.A573P | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59389941; called by muse, mutect2, varscan2
- COL24A1 | c.1060C>A p.H354N | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV65302307; called by muse, mutect2, varscan2
- COL27A1 | c.3167C>A p.P1056Q | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV61921793; called by muse, mutect2, varscan2
- COL7A1 | c.6696del p.G2233Afs*155 | Frame Shift Del (DEL) | VAF 5/30 reads (17%) | catalogued as rs749256529, COSV60404899; called by mutect2, pindel, varscan2
- COPB1 | c.2734G>T p.E912* | Nonsense Mutation (SNP) | VAF 11/75 reads (15%) | catalogued as COSV51446811; called by muse, mutect2, varscan2
- COX10 | c.1307G>T p.G436V | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.01); catalogued as COSV55402452; called by muse, mutect2, varscan2
- CPED1 | c.1025G>T p.S342I | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.836); catalogued as COSV59997522; called by muse, mutect2, varscan2
- CPED1 | c.2996C>G p.S999W | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59997531, COSV59999791; called by muse, mutect2, varscan2
- CR1L | c.113C>A p.P38Q | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99686884, COSV99687235; called by muse, mutect2, varscan2
- CREBBP | c.682A>G p.T228A | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV52114684; called by muse, mutect2, varscan2
- CRY1 | c.1001G>T p.R334L | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); catalogued as COSV50481121, COSV50484306; called by muse, mutect2, varscan2
- CSAG2 | c.374G>T p.G125V | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as rs1171287971; called by mutect2, varscan2
- CSHL1 | c.285G>T p.M95I (on ENST00000309894 / NM_022581.3; = p.M1? on NM_001318.4) | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as COSV51987258, COSV99368274; called by muse, mutect2, varscan2
- CSMD1 | c.6359T>A p.L2120Q (on ENST00000520002; = p.L2119Q on NM_033225.6) | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59284358; called by muse, mutect2, varscan2
- CSMD3 | c.9146C>T p.S3049L (on ENST00000297405 / NM_001363185.1; = p.S2880L on NM_052900.3) | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52108048; called by muse, mutect2, varscan2
- CSMD3 | c.2381C>A p.A794D (on ENST00000297405 / NM_001363185.1; = p.A690D on NM_052900.3) | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.48); PolyPhen probably damaging (1); catalogued as COSV52108063; called by muse, mutect2, varscan2
- DACH1 | c.1332C>A p.S444R (on ENST00000619232 / NM_001366712.1; = p.S392R on NM_080759.6) | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV57490224; called by muse, mutect2
- DCP1A | c.1391A>T p.Q464L | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as COSV53687444; called by muse, mutect2
- DCX | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 36/59 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as CM010015, COSV57566171; called by muse, mutect2, varscan2
- DDR1 | c.2173G>C p.G725R (on ENST00000324771; = p.G688R on NM_001954.4) | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.088); catalogued as COSV61319307; called by muse, mutect2, varscan2
- DDX53 | c.257A>G p.N86S | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as COSV60068524; called by muse, mutect2, varscan2
- DDX60 | c.265G>T p.D89Y | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV67095207; called by muse, mutect2, varscan2
- DGKK | c.3364G>C p.G1122R | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.452); catalogued as COSV65706458; called by muse, mutect2, varscan2
- DLG5 | c.767G>T p.R256L | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.544); catalogued as COSV64946863; called by muse, mutect2, varscan2
- DMBT1 | c.787T>C p.W263R | Missense Mutation (SNP) | VAF 51/230 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57535125; called by muse, mutect2
- DMBT1 | c.789G>A p.W263* | Nonsense Mutation (SNP) | VAF 51/228 reads (22%) | catalogued as COSV57535147; called by muse, mutect2
- DMD | c.8960C>A p.P2987H | Missense Mutation (SNP) | VAF 41/65 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58893010; called by muse, mutect2, varscan2
- DMD | c.4253C>G p.T1418R | Missense Mutation (SNP) | VAF 37/54 reads (69%) | SIFT tolerated (0.21); PolyPhen benign (0.054); catalogued as COSV63736048; called by muse, mutect2, varscan2
- DNAH9 | c.3518T>C p.I1173T | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.175); catalogued as COSV52335299; called by muse, mutect2, varscan2
- DNAH9 | c.9037A>T p.K3013* | Nonsense Mutation (SNP) | VAF 33/84 reads (39%) | catalogued as COSV52335315; called by muse, mutect2, varscan2
- DNAJC6 | c.1165A>G p.S389G | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as COSV54770077; called by muse, mutect2, varscan2
- DOCK10 | c.4004G>T p.R1335M | Missense Mutation (SNP) | VAF 34/159 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51349240; called by muse, mutect2, varscan2
- DPY19L2 | c.1580+1G>T p.X527_splice | Splice Site (SNP) | VAF 11/25 reads (44%) | catalogued as COSV60541378; called by muse, mutect2, varscan2
- DRC7 | c.378+1G>T p.X126_splice | Splice Site (SNP) | VAF 28/132 reads (21%) | catalogued as COSV61053143; called by muse, mutect2, varscan2
- DROSHA | c.2451G>T p.K817N | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as COSV60772753; called by muse, mutect2, varscan2
- DSG1 | c.1723G>A p.G575S | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.026); catalogued as COSV57133353; called by muse, mutect2, varscan2
- DSP | c.3857A>T p.Q1286L | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.932); catalogued as COSV65791330; called by muse, mutect2, varscan2
- DTNBP1 | c.811+5G>C | Splice Region (SNP) | VAF 14/98 reads (14%) | catalogued as COSV100160439; called by muse, mutect2, varscan2
- DUOX1 | c.4427A>G p.Q1476R | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52049419; called by muse, mutect2, varscan2
- DUSP19 | c.442G>C p.V148L | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); catalogued as COSV61192814; called by muse, mutect2, varscan2
- DYSF | c.3153C>A p.S1051R | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.147); catalogued as COSV50270235; called by muse, mutect2, varscan2
- DYSF | c.4198C>A p.P1400T | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV99244852; called by muse, mutect2, varscan2
- EEF1AKMT1 | c.136G>T p.E46* | Nonsense Mutation (SNP) | VAF 21/76 reads (28%) | catalogued as COSV66964403; called by muse, mutect2, varscan2
- EHHADH | c.1347A>T p.Q449H | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.364); catalogued as COSV51627841; called by muse, mutect2, varscan2
- EHMT1 | c.323A>T p.H108L | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.122); catalogued as COSV58371160; called by muse, mutect2, varscan2
- EIF1AD | c.305G>T p.W102L | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56463288; called by muse, mutect2
- ELAPOR2 | c.2797G>T p.G933C (on ENST00000450689 / NM_001142749.3; = p.G766C on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); catalogued as rs776339060, COSV51884564, COSV51891560, COSV99788294; called by muse, mutect2, varscan2
- ELOA2 | c.1558C>A p.P520T | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs202182645, COSV55293952; called by muse, mutect2, varscan2
- EMCN | c.64G>T p.G22C | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.665); catalogued as COSV56456800; called by muse, mutect2, varscan2
- EMSY | c.3712A>T p.M1238L | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV58257581; called by muse, mutect2
- EMSY | c.3714G>T p.M1238I | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV58257592; called by muse, mutect2
- ENAM | c.3359C>A p.P1120Q | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV68535268; called by muse, mutect2, varscan2
- ENGASE | c.341G>T p.R114L | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV56134313, COSV56136734; called by muse, mutect2, varscan2
- ENGASE | c.1289A>T p.Q430L | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV56134321; called by muse, mutect2, varscan2
- ENTR1 | c.458G>T p.G153V (on ENST00000357365 / NM_001039707.2; = p.G130V on NM_006643.4) | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV53740680, COSV53741953; called by muse, mutect2
- ESRRG | c.630C>A p.Y210* | Nonsense Mutation (SNP) | VAF 8/63 reads (13%) | catalogued as COSV63150606; called by muse, mutect2, varscan2
- EXT1 | c.2093T>C p.F698S | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.906); catalogued as COSV65475319; called by muse, mutect2, varscan2
- FAM135B | c.3889A>T p.S1297C | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52706704; called by muse, mutect2, varscan2
- FAM13C | c.719G>A p.R240Q | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768651945, COSV53243574; called by muse, mutect2, varscan2
- FAM83C | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV65582100; called by muse, mutect2, varscan2
- FAM83H | c.2620G>T p.A874S | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.242); catalogued as rs372449536; called by muse, mutect2
- FAM9B | c.253C>T p.H85Y | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as rs943864023, COSV59119077; called by muse, mutect2
- FAP | c.2212G>T p.G738C | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99501808; called by muse, mutect2, varscan2
- FBLN2 | c.1739C>T p.A580V | Missense Mutation (SNP) | VAF 48/120 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV55480964; called by muse, mutect2, varscan2
- FBN1 | c.6613G>A p.E2205K | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.152); catalogued as COSV57309946; called by muse, mutect2, varscan2
- FECH | c.1077+1G>T p.X359_splice | Splice Site (SNP) | VAF 34/171 reads (20%) | catalogued as rs786205245, CS930809, COSV50490307; called by muse, mutect2, varscan2
- FEM1B | c.200A>G p.E67G | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.173); catalogued as COSV60987834; called by muse, mutect2, varscan2
- FERD3L | c.200G>T p.C67F | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV51761664; called by muse, mutect2
- FGF12 | c.304G>T p.D102Y (on ENST00000454309 / NM_021032.5; = p.D40Y on NM_004113.6) | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV53153576, COSV53168571; called by muse, mutect2, varscan2
- FGL2 | c.583C>A p.P195T | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as COSV50380254; called by muse, mutect2, varscan2
- FHOD3 | c.3226C>A p.Q1076K (on ENST00000359247 / NM_001281739.3; = p.Q1093K on NM_025135.5) | Missense Mutation (SNP) | VAF 32/186 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV57165034; called by muse, mutect2, varscan2
- FIGLA | c.514G>C p.G172R | Missense Mutation (SNP) | VAF 19/265 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0.031); catalogued as rs782623686, COSV60088706; called by muse, mutect2
- FLG | c.11441G>A p.R3814H | Missense Mutation (SNP) | VAF 54/439 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.964); catalogued as rs746397911, COSV64236909; called by muse, mutect2, varscan2
- FLG | c.1370G>T p.R457L | Missense Mutation (SNP) | VAF 28/211 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.735); catalogued as rs374511333, COSV100910716; called by muse, mutect2, varscan2
- FOXE3 | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs367943249, CM163143, COSV100624042, COSV58632486; called by muse, mutect2
- FOXG1 | c.733C>A p.H245N | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as COSV57395332, COSV57396519; called by muse, mutect2, varscan2
- FREM2 | c.3229G>T p.V1077L | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV54829379; called by muse, mutect2, varscan2
- FRMD7 | c.1573C>A p.P525T | Missense Mutation (SNP) | VAF 57/151 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as COSV53744727, COSV53745506; called by muse, mutect2, varscan2
- FSCB | c.2156C>A p.P719Q | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as COSV100468926; called by mutect2, varscan2
- FYN | c.315A>T p.K105N | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57610006; called by muse, mutect2, varscan2
- GABBR2 | c.2301G>T p.K767N | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.521); catalogued as COSV52293973; called by muse, mutect2, varscan2
- GABRB3 | c.973G>C p.A325P | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54651284; called by muse, mutect2, varscan2
- GABRG1 | c.941C>A p.T314K | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54950269; called by muse, mutect2, varscan2
- GABRG1 | c.511T>G p.W171G | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.392); catalogued as COSV54950273; called by muse, mutect2
- GBA3 | c.325A>G p.K109E | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV101545459, COSV72437864; called by muse, mutect2, varscan2
- GBP6 | c.67G>T p.V23L | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.253); catalogued as COSV65010751; called by muse, mutect2, varscan2
- GDF6 | c.1268C>A p.T423N | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV54622952; called by muse, mutect2, varscan2
- GIMAP1 | c.578C>G p.T193S | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.241); catalogued as COSV100211971, COSV56189224; called by muse, mutect2, varscan2
- GLIS1 | c.1124A>G p.Q375R | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.183); catalogued as COSV56544140; called by muse, mutect2
- GNAZ | c.299G>T p.R100L | Missense Mutation (SNP) | VAF 44/182 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs746553162, COSV50736965, COSV50739350; called by muse, mutect2, varscan2
- GOLGA5 | c.769G>T p.E257* | Nonsense Mutation (SNP) | VAF 10/31 reads (32%) | catalogued as COSV50832036, COSV99371381; called by muse, mutect2, varscan2
- GON4L | c.4189C>T p.P1397S | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.005); catalogued as rs751363939, COSV55187465; called by muse, mutect2, varscan2
- GP2 | c.923T>C p.I308T (on ENST00000381362 / NM_001007240.3; = p.I305T on NM_001502.4) | Missense Mutation (SNP) | VAF 50/193 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as COSV56892131; called by muse, mutect2, varscan2
- GP2 | c.249G>T p.Q83H | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV56892141; called by muse, mutect2, varscan2
- GPATCH1 | c.709G>T p.A237S | Missense Mutation (SNP) | VAF 129/213 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.08); catalogued as COSV50111411; called by muse, mutect2, varscan2
- GPATCH2L | c.223G>T p.D75Y | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.935); catalogued as rs140112317; called by muse, mutect2, varscan2
- GPATCH8 | c.3498G>T p.L1166F | Missense Mutation (SNP) | VAF 49/184 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.093); catalogued as COSV59193272; called by muse, mutect2, varscan2
- GPR137C | c.910G>C p.G304R | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100397465, COSV58704010; called by muse, mutect2, varscan2
- GPR55 | c.116T>A p.L39Q | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); catalogued as COSV67407089; called by muse, mutect2, varscan2
- GPR63 | c.587A>T p.K196M | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57739652; called by muse, mutect2, varscan2
- GREM1 | c.88C>G p.Q30E | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.13); catalogued as COSV55714418; called by muse, mutect2, varscan2
- GRID2 | c.1781G>T p.R594L | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.21); catalogued as COSV56175430, COSV56182504; called by muse, mutect2, varscan2
- GRIK2 | c.476C>A p.A159D | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59713577, COSV59737795; called by muse, mutect2, varscan2
- GRM8 | c.2264A>G p.Y755C | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58804184; called by muse, mutect2, varscan2
- GTDC1 | c.517A>T p.S173C | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV53988562; called by muse, mutect2, varscan2
- H2BC7 | c.254A>G p.N85S | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.123); catalogued as rs1408704235, COSV61911565; called by muse, mutect2, varscan2
- HDX | c.808G>T p.V270F | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV52973250; called by muse, mutect2, varscan2
- HELZ2 | c.7222C>T p.R2408W (on ENST00000467148 / NM_001037335.2; = p.R1839W on NM_033405.3) | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs747775785, COSV64442485; called by muse, mutect2, varscan2
- HHIPL2 | c.1760C>A p.A587D | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV58563293; called by muse, mutect2, varscan2
- HHIPL2 | c.1015G>T p.G339C | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58563302; called by muse, mutect2, varscan2
- HIGD1C | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV68250588; called by muse, mutect2, varscan2
- HIRA | c.517C>T p.H173Y | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54272274; called by muse, mutect2, varscan2
- HMCN1 | c.10771-1G>A p.X3591_splice | Splice Site (SNP) | VAF 14/89 reads (16%) | catalogued as COSV54879121; called by muse, mutect2, varscan2
- HNMT | c.423G>T p.M141I | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV54506091, COSV54508484; called by muse, mutect2
- HNRNPH2 | c.680G>T p.G227V | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.963); catalogued as COSV54508155; called by muse, mutect2, varscan2
- HOPX | c.116A>T p.E39V (on ENST00000317745; = p.E57V on NM_032495.6) | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.311); catalogued as COSV58499492; called by muse, mutect2, varscan2
- HOXD10 | c.163C>A p.P55T | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as COSV50898234; called by muse, mutect2, varscan2
- HOXD12 | c.334C>T p.R112C | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.819); catalogued as COSV66832326; called by muse, mutect2, varscan2
- HS1BP3 | c.436A>T p.T146S | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV58311971; called by muse, mutect2, varscan2
- HSD11B1 | c.325C>T p.L109F | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.678); catalogued as rs780563325, COSV54826019; called by muse, mutect2, varscan2
- HUWE1 | c.145T>C p.C49R | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV53335397; called by muse, mutect2, varscan2
- IDH3G | c.349A>T p.N117Y | Missense Mutation (SNP) | VAF 60/106 reads (57%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.943); catalogued as COSV54206141; called by muse, mutect2, varscan2
- IFI44L | c.868A>T p.R290* | Nonsense Mutation (SNP) | VAF 9/76 reads (12%) | catalogued as COSV60726738; called by muse, mutect2, varscan2
- IFT140 | c.652G>T p.D218Y | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV68486029; called by muse, mutect2, varscan2
- IGKV1D-16 | c.257G>A p.G86D | Missense Mutation (SNP) | VAF 61/208 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as rs373137298; called by muse, mutect2, varscan2
- IGSF10 | c.3032G>T p.G1011V | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV56781094; called by muse, varscan2
- IGSF22 | c.2293C>T p.L765F (on ENST00000319338; = p.L866F on NM_173588.4) | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60031099; called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.1314G>C p.K438N (on ENST00000485419 / NM_001197113.1; = p.K362N on NM_014575.3) | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.856); catalogued as COSV61839147, COSV61839599, COSV61843001; called by muse, mutect2, varscan2
- IRX5 | c.1172C>T p.P391L | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.108); catalogued as COSV58058437; called by muse, mutect2, varscan2
- ISL1 | c.333C>A p.S111R | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.493); catalogued as COSV57932268; called by muse, mutect2, varscan2
- ITGA1 | c.1777G>C p.A593P | Missense Mutation (SNP) | VAF 35/62 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50876613; called by muse, mutect2, varscan2
- ITGA2 | c.3104T>A p.V1035E | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.326); catalogued as COSV56856598; called by muse, mutect2, varscan2
- ITGAX | c.1515G>T p.W505C | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.19); catalogued as rs758212587, COSV51641889; called by muse, mutect2, varscan2
- ITIH6 | c.1474G>T p.A492S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV54486707; called by muse, mutect2
- ITPRID2 | c.1430G>T p.G477V | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57469681; called by muse, mutect2, varscan2
- KCNA4 | c.122C>A p.A41E | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV60250819; called by muse, mutect2, varscan2
- KCNC2 | c.1279G>C p.G427R | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV54362845, COSV54381620; called by muse, varscan2
- KCNH8 | c.2109C>A p.N703K | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV60457149; called by muse, mutect2, varscan2
- KDM5A | c.790C>T p.R264* | Nonsense Mutation (SNP) | VAF 11/95 reads (12%) | catalogued as COSV66990462, COSV66990880; called by muse, mutect2, varscan2
- KHDRBS2 | c.844G>T p.D282Y | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV55428911; called by muse, mutect2, varscan2
- KIAA0232 | c.181G>A p.V61I | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV56923371; called by muse, mutect2, varscan2
- KIAA1109 | c.5977C>A p.P1993T | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.994); catalogued as COSV52663066, COSV52692161; called by muse, mutect2, varscan2
- KIF2B | c.1406C>A p.A469E | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52127268; called by muse, mutect2, varscan2
- KIF3A | c.1970A>G p.E657G | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.932); catalogued as COSV66413108; called by muse, mutect2, varscan2
- KIF4B | c.1257G>T p.R419S | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.096); catalogued as COSV70527915, COSV70527944; called by muse, mutect2, varscan2
- KIF4B | c.2046G>T p.R682S | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV70527954; called by muse, mutect2, varscan2
- KIFC2 | c.1653G>T p.Q551H | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.219); catalogued as rs763937224, COSV56760013; called by muse, mutect2, varscan2
- KLK11 | c.403C>T p.P135S (on ENST00000594768 / NM_144947.3; = p.P103S on NM_006853.3) | Missense Mutation (SNP) | VAF 48/83 reads (58%) | SIFT tolerated (0.28); PolyPhen benign (0.088); catalogued as COSV51575785; called by muse, mutect2, varscan2
- KMO | c.1234G>A p.V412M | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.073); catalogued as COSV59362617; called by muse, mutect2, varscan2
- KPRP | c.828G>T p.E276D | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.399); catalogued as rs757916101, COSV64221039; called by muse, mutect2
- KRTAP21-2 | c.95G>T p.G32V | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.906); catalogued as COSV61683888; called by muse, mutect2, varscan2
- LBP | c.637C>A p.L213I | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.919); catalogued as COSV54138738; called by muse, mutect2, varscan2
- LCN8 | c.363G>A p.M121I (on ENST00000612714 / NM_001345934.1; = p.M98I on NM_178469.3) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.027); catalogued as COSV60209344; called by muse, mutect2
- LCT | c.5111+1G>T p.X1704_splice | Splice Site (SNP) | VAF 21/62 reads (34%) | catalogued as COSV51544483; called by muse, mutect2, varscan2
- LGR5 | c.881A>G p.Q294R | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.852); catalogued as rs1453187121, COSV57002460; called by muse, mutect2, varscan2
- LGR6 | c.1244C>A p.P415H (on ENST00000367278 / NM_001017403.1; = p.P363H on NM_021636.3) | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99706255, COSV99706353; called by muse, mutect2, varscan2
- LMO7 | c.4476-2A>T p.X1492_splice (on ENST00000357063; = p.X1173_splice on NM_005358.5) | Splice Site (SNP) | VAF 8/30 reads (27%) | catalogued as COSV58530483; called by muse, mutect2, varscan2
- LMOD1 | c.172C>T p.Q58* | Nonsense Mutation (SNP) | VAF 17/71 reads (24%) | catalogued as COSV66171903; called by muse, mutect2, varscan2
- LPA | c.4045A>G p.T1349A | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.911); catalogued as COSV60297322; called by muse, mutect2, varscan2
- LRP1B | c.11711C>A p.P3904Q | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV67188710; called by muse, mutect2, varscan2
- LRP1B | c.6208G>T p.E2070* | Nonsense Mutation (SNP) | VAF 31/112 reads (28%) | catalogued as COSV67188717; called by muse, mutect2, varscan2
- LRP4 | c.2258G>T p.R753L | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV66134097; called by muse, mutect2, varscan2
- LRRC32 | c.341C>A p.A114E | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.029); catalogued as COSV52631603; called by muse, mutect2, varscan2
- LRRC4B | c.1400G>T p.G467V | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.012); catalogued as COSV65349273; called by muse, mutect2, varscan2
- LRRC52 | c.16G>T p.G6C | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV54231321; called by muse, mutect2, varscan2
- LRRC6 | c.626G>A p.R209H | Missense Mutation (SNP) | VAF 29/262 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs760693690, COSV51538117; called by muse, mutect2, varscan2
- LRRC7 | c.475G>T p.E159* (on ENST00000651989 / NM_001370785.2; = p.E126* on NM_001330635.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 6/61 reads (10%) | catalogued as COSV50413198; called by muse, mutect2
- LRRC7 | c.1832C>G p.P611R (on ENST00000651989 / NM_001370785.2; = p.P578R on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1030286536, COSV50413291; called by muse, mutect2, varscan2
- LRTM1 | c.642C>A p.D214E | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs200962085, COSV55516452; called by muse, mutect2, varscan2
- LTBP1 | c.3731-2A>C p.X1244_splice (on ENST00000404816 / NM_206943.4; = p.X918_splice on NM_000627.4) | Splice Site (SNP) | VAF 29/126 reads (23%) | catalogued as COSV55375786; called by muse, mutect2, varscan2
- MACF1 | c.11927C>G p.A3976G (on ENST00000372915; = p.A1909G on NM_012090.5) | Missense Mutation (SNP) | VAF 11/20 reads (55%) | catalogued as COSV57107433; called by muse, mutect2, varscan2
- MACROH2A1 | c.80G>T p.R27L | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56893405, COSV56893453; called by muse, mutect2, varscan2
- MAGEA10 | c.280C>A p.P94T | Missense Mutation (SNP) | VAF 53/135 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.411); catalogued as COSV54882942; called by muse, mutect2, varscan2
- MAGEA4 | c.908del p.P303Hfs*9 | Frame Shift Del (DEL) | VAF 30/77 reads (39%) | catalogued as COSV52340802; called by mutect2, pindel, varscan2
- MAGEL2 | c.3445C>T p.L1149F | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.027); catalogued as rs1222277101, COSV58565991; called by muse, mutect2, varscan2
- MAML1 | c.618G>C p.E206D | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV52983173; called by muse, mutect2, varscan2
- MAN1A2 | c.1180G>T p.V394F | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as COSV62976340; called by muse, varscan2
- MARCHF6 | c.1786G>A p.A596T | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.46); PolyPhen benign (0.017); catalogued as COSV56878932; called by muse, mutect2, varscan2
- MBL2 | c.319C>A p.L107M | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.15); catalogued as COSV64758014; called by muse, mutect2, varscan2
- MED13L | c.317A>T p.E106V | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV56116090, COSV56119655; called by muse, mutect2, varscan2
- MEP1A | c.1385C>A p.S462* | Nonsense Mutation (SNP) | VAF 24/65 reads (37%) | catalogued as COSV57918066, COSV57922496; called by muse, mutect2, varscan2
- MICALL2 | c.192+1G>T p.X64_splice | Splice Site (SNP) | VAF 33/120 reads (28%) | catalogued as COSV52514155; called by muse, mutect2, varscan2
- MLIP | c.857G>C p.R286T | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.014); catalogued as rs1284187710, COSV51426112; called by muse, mutect2, varscan2
- MLLT10 | c.515A>T p.Q172L | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV56991517; called by muse, mutect2, varscan2
- MMD2 | c.758C>T p.A253V (on ENST00000404774 / NM_001100600.2; = p.A229V on NM_198403.4) | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1362205044, COSV68659768; called by muse, mutect2, varscan2
- MMP8 | c.606G>C p.W202C | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52631155; called by muse, mutect2, varscan2
- MMP9 | c.1611G>T p.G537= | Splice Region (SNP) | VAF 9/32 reads (28%) | catalogued as COSV63433779; called by muse, mutect2, varscan2
- MNDA | c.862G>T p.D288Y | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as COSV63739978; called by muse, mutect2, varscan2
- MOCS1 | c.895G>T p.G299C | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57933681; called by muse, mutect2, varscan2
- MOGS | c.895G>T p.G299C | Missense Mutation (SNP) | VAF 38/184 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs746113375, COSV99270343, COSV99270698; called by muse, mutect2, varscan2
- MRTFA | c.2253G>T p.K751N | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.093); catalogued as COSV100843880; called by muse, mutect2, varscan2
- MS4A14 | c.694G>T p.E232* | Nonsense Mutation (SNP) | VAF 33/85 reads (39%) | catalogued as COSV100280639, COSV55733242; called by muse, mutect2, varscan2
- MS4A8 | c.548C>T p.A183V | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.253); catalogued as rs758725009, COSV55753158; called by muse, mutect2, varscan2
- MSH4 | c.776T>A p.I259K | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as COSV54196945; called by muse, mutect2, varscan2
- MUC17 | c.4801A>C p.K1601Q | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV60280780; called by muse, mutect2, varscan2
- MUSK | c.1653C>A p.N551K | Missense Mutation (SNP) | VAF 33/160 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99503755; called by muse, mutect2, varscan2
- MYBPC3 | c.3002C>T p.P1001L | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57023456; called by muse, mutect2, varscan2
- MYH15 | c.2605G>A p.A869T | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.011); catalogued as COSV56304706; called by muse, mutect2
- MYO18B | c.7051T>A p.C2351S | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); catalogued as COSV59126057; called by muse, mutect2, varscan2
- MYO3A | c.3884A>G p.Y1295C | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV56320531; called by muse, mutect2, varscan2
- MYT1L | c.2558G>T p.R853L | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.229); catalogued as COSV101219097, COSV67726880; called by muse, mutect2, varscan2
- NAP1L4 | c.703G>T p.D235Y | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as COSV65880570; called by muse, mutect2, varscan2
- NDST4 | c.956G>T p.R319M | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52109665; called by muse, mutect2, varscan2
- NEU2 | c.790C>A p.L264M | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99290470; called by mutect2, varscan2
- NKX2-4 | c.1003G>T p.A335S | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV61084900; called by muse, mutect2
- NLGN1 | c.584G>A p.S195N | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs760953059, COSV100848736, COSV64324106; called by muse, mutect2, varscan2
- NLRP10 | c.1247T>C p.L416P | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60778764; called by muse, mutect2, varscan2
- NMUR2 | c.490C>A p.L164I | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.824); catalogued as COSV54917219, COSV54918593, COSV54922498; called by muse, mutect2, varscan2
- NPAS2 | c.944G>T p.R315L | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100175876; called by muse, mutect2, varscan2
- NPAT | c.640G>T p.E214* | Nonsense Mutation (SNP) | VAF 23/62 reads (37%) | catalogued as COSV53716091; called by muse, mutect2, varscan2
- NPFFR2 | c.710C>T p.T237M | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749449981, COSV58146543; called by muse, mutect2
- NR2E1 | c.619T>C p.S207P | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.295); catalogued as COSV64561444; called by muse, mutect2, varscan2
- NRAP | c.3898G>T p.G1300* (on ENST00000359988 / NM_001322945.2; = p.G1265* on NM_006175.4) | Nonsense Mutation (SNP) | VAF 65/326 reads (20%) | catalogued as COSV63488608; called by muse, mutect2, varscan2
- NRL | c.373C>A p.H125N | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV53742601; called by muse, mutect2, varscan2
- NUDT12 | c.291A>T p.L97F | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.767); catalogued as COSV50090400, COSV50092203; called by muse, mutect2, varscan2
- NUP155 | c.946G>T p.A316S (on ENST00000231498 / NM_153485.3; = p.A257S on NM_004298.4) | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.417); catalogued as COSV51527147; called by muse, mutect2, varscan2
- NUP214 | c.1178C>T p.S393L | Missense Mutation (SNP) | VAF 7/130 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63907782; called by muse, mutect2
- OBSCN | c.8393A>T p.E2798V | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.707); catalogued as COSV52743059; called by muse, mutect2, varscan2
- OR10H2 | c.293C>A p.A98D | Missense Mutation (SNP) | VAF 48/120 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV100008874, COSV59945428; called by muse, mutect2
- OR10K1 | c.708G>T p.K236N | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV56870654; called by muse, mutect2, varscan2
- OR11H1 | c.754G>T p.V252L | Missense Mutation (SNP) | VAF 57/256 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as COSV99421612; called by muse, mutect2, varscan2
- OR12D2 | c.758C>A p.P253H | Missense Mutation (SNP) | VAF 17/160 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65826453, COSV65830610; called by muse, mutect2, varscan2
- OR14K1 | c.724C>A p.H242N | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV99314992; called by muse, mutect2
- OR2AT4 | c.88C>T p.L30F | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.038); catalogued as rs1565514295, COSV59406368; called by muse, mutect2, varscan2
- OR2D2 | c.323G>T p.G108V | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV55056412; called by muse, mutect2, varscan2
- OR2G6 | c.119T>C p.L40P | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as rs1283707535, COSV58573747; called by muse, mutect2, varscan2
- OR4D2 | c.11G>A p.G4E | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT tolerated (0.85); PolyPhen benign (0.005); catalogued as COSV73459700; called by muse, mutect2, varscan2
- OR4K1 | c.542T>A p.L181H | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53458880; called by muse, mutect2
- OR4K15 | c.626C>A p.T209N (on ENST00000305051; = p.T185N on NM_001005486.1) | Missense Mutation (SNP) | VAF 27/251 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV59300437; called by muse, mutect2, varscan2
- OR51B6 | c.409A>T p.T137S | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV66512265; called by muse, mutect2
- OR51G1 | c.361T>A p.S121T | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.469); catalogued as rs1421018309, COSV58968493; called by muse, mutect2
- OR52E8 | c.474C>A p.S158R | Missense Mutation (SNP) | VAF 48/144 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as rs753051339, COSV66204940; called by muse, mutect2, varscan2
- OR52N5 | c.268G>T p.A90S | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as COSV57698488; called by muse, mutect2, varscan2
- OR5C1 | c.773C>A p.T258K | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV65455866; called by muse, mutect2, varscan2
- OR5D16 | c.433A>C p.M145L | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV65721346; called by muse, mutect2, varscan2
- OR5H14 | c.796C>A p.Q266K | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.45); PolyPhen benign (0.06); catalogued as COSV71193499; called by muse, mutect2, varscan2
- OR6B1 | c.525C>A p.N175K | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV68769796; called by muse, mutect2, varscan2
- OR8J1 | c.106G>A p.G36R | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.701); catalogued as COSV57316680; called by muse, mutect2, varscan2
- OSBPL6 | c.1175C>T p.A392V | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.612); catalogued as COSV51911357; called by muse, mutect2, varscan2
- P2RX3 | c.256-2A>G p.X86_splice | Splice Site (SNP) | VAF 4/46 reads (9%) | catalogued as COSV54441522; called by muse, mutect2
- PABPC3 | c.347A>C p.Y116S | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV55797538, COSV55800740; called by muse, varscan2
- PADI4 | c.293G>T p.G98V | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV64923078; called by muse, mutect2, varscan2
- PAK5 | c.1919A>C p.E640A | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62021566; called by muse, mutect2, varscan2
- PAQR9 | c.626A>T p.Y209F | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.79); PolyPhen benign (0.023); catalogued as COSV61417644; called by muse, mutect2, varscan2
- PARP9 | c.1582T>A p.Y528N | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV64449980; called by muse, mutect2, varscan2
- PBX3 | c.218G>T p.C73F | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV60730613; called by muse, mutect2, varscan2
- PCDH10 | c.2723C>A p.S908Y | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV52087904; called by muse, mutect2, varscan2
- PCDH11X | c.1923C>A p.F641L | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as COSV53481060; called by muse, mutect2, varscan2
- PCDH15 | c.1836C>A p.S612R | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.667); catalogued as rs200226791, COSV57265782; called by muse, mutect2, varscan2
- PCDH9 | c.2464G>T p.G822C | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV60528931, COSV60530371; called by muse, mutect2, varscan2
- PCDH9 | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0.439); catalogued as COSV60530381; called by muse, mutect2, varscan2
- PCDHB14 | c.1082C>A p.S361* | Nonsense Mutation (SNP) | VAF 17/57 reads (30%) | catalogued as COSV53386610; called by muse, mutect2, varscan2
- PCDHGA12 | c.938G>T p.G313V | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.024); catalogued as rs1303639699, COSV52744281; called by muse, mutect2, varscan2
- PCDHGB1 | c.319G>T p.A107S | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.294); catalogued as rs1172761775, COSV53902887, COSV53959411; called by muse, mutect2, varscan2
- PCM1 | c.3963G>A p.M1321I | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0.018); catalogued as COSV59585333; called by muse, mutect2, varscan2
- PCOLCE2 | c.626G>T p.R209L | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs138409602, COSV55997655; called by muse, mutect2, varscan2
- PCSK5 | c.2618G>T p.C873F | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV65083941; called by muse, mutect2, varscan2
- PGC | c.1036G>T p.G346* | Nonsense Mutation (SNP) | VAF 7/28 reads (25%) | catalogued as COSV57823628; called by muse, mutect2, varscan2
- PGM2 | c.1019G>A p.R340K | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs538140719, COSV67938398; called by muse, varscan2
- PHKA1 | c.2729G>T p.G910V | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as rs782722259, COSV100263155, COSV59801958; called by muse, mutect2, varscan2
- PHLPP1 | c.3027G>C p.E1009D | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.034); catalogued as COSV53022814; called by muse, mutect2, varscan2
- PLXND1 | c.5250G>T p.K1750N | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60709597; called by muse, mutect2
- PMPCB | c.724G>T p.A242S | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.238); catalogued as COSV50785526, COSV50785906; called by muse, mutect2, varscan2
- PNLIP | c.1330A>G p.K444E | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV65039749; called by muse, mutect2, varscan2
- POSTN | c.2492G>A p.R831K | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.078); catalogued as COSV65711931; called by muse, mutect2, varscan2
- PPFIA1 | c.962G>T p.R321I | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV54131730; called by muse, mutect2, varscan2
- PPP1R18 | c.424G>T p.E142* | Nonsense Mutation (SNP) | VAF 21/151 reads (14%) | catalogued as COSV51294659; called by muse, mutect2, varscan2
- PPP1R3A | c.3321G>T p.W1107C | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.24); catalogued as COSV52876906; called by muse, mutect2, varscan2
- PPP3CB | c.226G>C p.E76Q | Missense Mutation (SNP) | VAF 42/184 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV61151001; called by muse, mutect2, varscan2
- PRDM1 | c.2387A>C p.D796A | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.318); catalogued as rs1365737017, COSV64844469; called by muse, mutect2, varscan2
- PREX2 | c.3328G>T p.D1110Y | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV55752085; called by muse, varscan2
- PREX2 | c.4603C>G p.R1535G | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV55752095, COSV55765100; called by muse, mutect2, varscan2
- PRKCE | c.2063G>T p.R688L | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV60312956, COSV60330060; called by muse, mutect2, varscan2
- PRKDC | c.4631del p.G1544Afs*29 | Frame Shift Del (DEL) | VAF 12/62 reads (19%) | catalogued as COSV58052371; called by pindel, varscan2
- PROX1 | c.707G>T p.R236L | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.868); catalogued as COSV54776187, COSV54785503; called by muse, mutect2, varscan2
- PRRT2 | c.517G>T p.E173* | Nonsense Mutation (SNP) | VAF 15/45 reads (33%) | catalogued as COSV54881510; called by muse, mutect2, varscan2
- PRSS35 | c.1008C>A p.Y336* | Nonsense Mutation (SNP) | VAF 12/68 reads (18%) | catalogued as COSV63800131; called by muse, mutect2, varscan2
- PSAPL1 | c.221C>A p.A74D | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); catalogued as COSV59842344; called by muse, mutect2
- PSG8 | c.1037C>A p.S346* | Nonsense Mutation (SNP) | VAF 132/222 reads (59%) | catalogued as COSV60609541; called by muse, mutect2, varscan2
- PSTPIP2 | c.605G>T p.R202L | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV68957515; called by muse, mutect2, varscan2
- PTGER3 | c.929C>T p.T310I | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.113); catalogued as rs769489266, COSV60687953; called by muse, mutect2, varscan2
- PTGFRN | c.2230G>T p.V744L | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as COSV67797787; called by muse, mutect2, varscan2
- PTPN18 | c.719G>A p.C240Y | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51558080; called by muse, mutect2, varscan2
- PTPRT | c.3220C>T p.P1074S | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.3); catalogued as COSV61962063; called by muse, mutect2, varscan2
- PTPRT | c.2436C>A p.S812R | Missense Mutation (SNP) | VAF 80/293 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV61962074, COSV61986179; called by muse, mutect2, varscan2
- PXDNL | c.3908G>T p.R1303M | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); catalogued as COSV62479037; called by muse, mutect2, varscan2
- PXDNL | c.3406G>A p.D1136N | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62478201; called by muse, mutect2, varscan2
- PXDNL | c.1483G>T p.G495W | Missense Mutation (SNP) | VAF 20/164 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100681932; called by muse, varscan2
- RABGGTB | c.121A>T p.M41L | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60636907; called by muse, mutect2, varscan2
- RALB | c.507C>A p.F169L | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.63); catalogued as COSV55602098; called by muse, mutect2
- RASGRF1 | c.133G>T p.A45S | Missense Mutation (SNP) | VAF 48/114 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.273); catalogued as COSV69176719; called by muse, mutect2, varscan2
- RASGRP4 | c.62G>T p.R21L | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as COSV53094097; called by muse, mutect2, varscan2
- RBMXL1 | c.509T>A p.L170Q | Missense Mutation (SNP) | VAF 51/218 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV53098229, COSV53098712; called by muse, varscan2
- RBP1 | c.20G>T p.G7V (on ENST00000619087 / NM_001365940.2; = p.G69V on NM_002899.5) | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51675674; called by muse, mutect2, varscan2
- RELCH | c.157G>T p.G53C | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.303); catalogued as COSV56882442; called by muse, mutect2, varscan2
- RGS7 | c.797A>C p.Q266P | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.646); catalogued as COSV58531432; called by muse, mutect2, varscan2
- RHD | c.487-1G>A p.X163_splice | Splice Site (SNP) | VAF 14/112 reads (13%) | catalogued as COSV59645307; called by muse, mutect2, varscan2
- RHNO1 | c.413G>T p.G138V | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.79); catalogued as COSV63485141; called by muse, mutect2, varscan2
- RIMS2 | c.2816C>A p.P939H (on ENST00000666250 / NM_001348490.2; = p.P747H on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV51654841; called by muse, mutect2, varscan2
- RNF123 | c.656G>A p.G219D | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59684468, COSV59686887; called by muse, mutect2, varscan2
- RPGRIP1 | c.2138C>G p.T713S | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV52845222, COSV52847544; called by muse, mutect2, varscan2
- RUVBL1 | c.368G>T p.R123L | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as COSV59474985; called by muse, mutect2, varscan2
- RYR1 | c.11120G>T p.R3707L | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.366); catalogued as rs193922838, CM064216, COSV62089595, COSV62100969; ClinVar: not provided; called by muse, mutect2, varscan2
- RYR2 | c.11798A>G p.Q3933R | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV63663915; called by muse, mutect2, varscan2
- RYR2 | c.12701C>G p.A4234G | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV63663920, COSV63708042; called by muse, mutect2, varscan2
- SALL1 | c.1989G>T p.L663F | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as COSV51753557; called by muse, mutect2, varscan2
- SALL3 | c.2404G>A p.E802K | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.27); catalogued as rs771174060, COSV73305780; called by muse, mutect2
- SALL3 | c.3134C>A p.P1045H | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV73305782; called by muse, mutect2, varscan2
- SATB1 | c.1390A>C p.I464L | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV58667650; called by muse, mutect2, varscan2
- SCAF4 | c.2705C>A p.P902H | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV54255565; called by muse, mutect2, varscan2
- SCFD1 | c.143A>T p.Y48F | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.993); catalogued as COSV61722306; called by muse, mutect2, varscan2
- SCFD2 | c.461T>C p.F154S | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as COSV101189434, COSV66368986; called by muse, mutect2
- SCN7A | c.2240dup p.N747Kfs*10 | Frame Shift Ins (INS) | VAF 13/56 reads (23%) | catalogued as rs1379314652; called by mutect2, pindel, varscan2
- SEC31A | c.3268G>T p.A1090S (on ENST00000355196 / NM_001318120.1; = p.A1051S on NM_016211.4) | Missense Mutation (SNP) | VAF 55/193 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.235); catalogued as COSV52341616; called by muse, mutect2, varscan2
- SELENOP | c.821A>G p.K274R | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); catalogued as COSV100736750; called by muse, mutect2, varscan2
- SERINC3 | c.634G>T p.A212S | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.231); catalogued as COSV54855470, COSV54856658; called by muse, mutect2, varscan2
- SERPINA12 | c.417C>A p.F139L | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57942295, COSV57946184; called by muse, mutect2, varscan2
- SERPINA5 | c.31C>T p.L11F | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.077); catalogued as rs773098572, COSV61573560; called by muse, mutect2, varscan2
- SERPINA9 | c.433C>A p.Q145K | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.115); catalogued as COSV54072968; called by muse, mutect2, varscan2
- SERPINB4 | c.20C>G p.A7G | Missense Mutation (SNP) | VAF 25/152 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV61984226; called by muse, mutect2, varscan2
- SETBP1 | c.1112G>A p.G371D | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.036); catalogued as COSV56313636; called by mutect2, varscan2
- SHISA3 | c.651C>A p.F217L | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.007); catalogued as COSV59979470, COSV59979893; called by muse, mutect2, varscan2
- SIGLEC10 | c.1483A>T p.T495S | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT tolerated (0.09); PolyPhen benign (0.377); catalogued as COSV59479079, COSV59482422; called by muse, mutect2, varscan2
- SIPA1L2 | c.3772A>T p.I1258F | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs1382240692, COSV53383972; called by muse, mutect2, varscan2
- SIRPB1 | c.712C>T p.P238S | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as COSV53537547; called by muse, mutect2, varscan2
- SLC22A8 | c.623C>A p.A208D | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV60323796, COSV60324120; called by muse, mutect2, varscan2
- SLC25A13 | c.1751-1G>T p.X584_splice | Splice Site (SNP) | VAF 10/98 reads (10%) | catalogued as COSV55703910; called by muse, mutect2
- SLC26A8 | c.100A>C p.T34P | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.143); catalogued as COSV62884637; called by muse, mutect2, varscan2
- SLC27A2 | c.352G>T p.V118L | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.025); catalogued as COSV51057530; called by muse, mutect2, varscan2
- SLC2A3 | c.395G>T p.G132V | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50000612; called by muse, mutect2, varscan2
- SLC6A3 | c.1686G>T p.W562C | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV54361760; called by muse, mutect2, varscan2
- SLC6A5 | c.1870-1G>C p.X624_splice | Splice Site (SNP) | VAF 19/129 reads (15%) | catalogued as COSV54223820; called by muse, mutect2, varscan2
- SLC9A1 | c.145T>G p.S49A | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as COSV56051162; called by muse, mutect2, varscan2
- SLC9C2 | c.228+1G>T p.X76_splice | Splice Site (SNP) | VAF 7/41 reads (17%) | catalogued as COSV62943950; called by muse, mutect2, varscan2
- SLCO1B1 | c.1223C>A p.A408D | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV57007381; called by muse, mutect2, varscan2
- SLCO4A1 | c.890C>T p.T297M | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.322); catalogued as rs373121417; called by muse, mutect2, varscan2
- SLIT2 | c.1529G>T p.C510F | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56561115; called by muse, mutect2
- SLIT3 | c.317A>T p.Q106L | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.281); catalogued as COSV60593714; called by muse, mutect2, varscan2
- SLITRK1 | c.1643G>T p.G548V | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.042); catalogued as COSV65674374; called by muse, mutect2
- SMAD1 | c.400+1G>T p.X134_splice | Splice Site (SNP) | VAF 18/139 reads (13%) | catalogued as COSV57470248, COSV57471281; called by muse, mutect2, varscan2
- SOX5 | c.843del p.V282Yfs*37 | Frame Shift Del (DEL) | VAF 36/96 reads (38%) | catalogued as COSV100508809, COSV58636393; called by mutect2, pindel, varscan2
- SOX6 | c.1655A>T p.Q552L (on ENST00000528429 / NM_001145819.2; = p.Q525L on NM_017508.3) | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV57037723; called by muse, mutect2
- SPAG16 | c.1237A>G p.S413G | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.688); catalogued as rs748900684, COSV59073136; called by muse, mutect2, varscan2
- SPATA17 | c.241-1G>C p.X81_splice | Splice Site (SNP) | VAF 17/104 reads (16%) | catalogued as COSV65119424; called by muse, mutect2, varscan2
- SPATA20 | c.1822G>T p.D608Y (on ENST00000356488 / NM_001258372.1; = p.D624Y on NM_022827.4) | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV50065853; called by muse, mutect2
- SPATA31E1 | c.4066C>A p.P1356T | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.09); catalogued as COSV57789589; called by muse, mutect2
- SPDL1 | c.948G>T p.Q316H | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV54667054; called by muse, mutect2, varscan2
- SPNS2 | c.1297del p.E433Rfs*53 | Frame Shift Del (DEL) | VAF 4/25 reads (16%) | catalogued as COSV100223881; called by mutect2, pindel
- SPTA1 | c.725T>C p.V242A | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs765274573, COSV63749293; called by muse, varscan2
- SRRM2 | c.82G>T p.G28C | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV57068662; called by muse, mutect2, varscan2
- STAB1 | c.6943G>C p.G2315R | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1473660085, COSV58732457; called by muse, mutect2, varscan2
- STN1 | c.598G>T p.D200Y | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV56544113; called by muse, mutect2, varscan2
- STXBP5L | c.1727C>T p.P576L | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.057); catalogued as rs747217368, COSV56501092; called by muse, mutect2, varscan2
- SULT1B1 | c.518G>C p.W173S | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60206662; called by muse, mutect2, varscan2
- SULT1E1 | c.137C>A p.P46H | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56947094; called by muse, mutect2, varscan2
- SYCE2 | c.457G>A p.V153M | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.654); catalogued as rs771075976, COSV53365499; called by muse, mutect2, varscan2
- SYCP1 | c.236A>T p.Q79L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.142); catalogued as COSV65694718; called by muse, mutect2, varscan2
- SYCP1 | c.2855G>C p.R952P | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV65694722, COSV65697586; called by muse, mutect2, varscan2
- TAAR6 | c.330C>A p.C110* | Nonsense Mutation (SNP) | VAF 26/135 reads (19%) | catalogued as COSV51582691; called by mutect2, varscan2
- TAF1L | c.5320G>T p.E1774* | Nonsense Mutation (SNP) | VAF 24/94 reads (26%) | catalogued as COSV54258366, COSV54266498; called by muse, mutect2, varscan2
- TAS2R40 | c.807C>G p.N269K | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV68818104; called by muse, mutect2
- TBX3 | c.838G>T p.A280S (on ENST00000257566 / NM_016569.4; = p.A260S on NM_005996.4) | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57469417, COSV57474588; called by muse, mutect2, varscan2
- TG | c.5362C>A p.Q1788K | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV55065871; called by muse, mutect2, varscan2
- TGDS | c.982+1G>A p.X328_splice | Splice Site (SNP) | VAF 12/48 reads (25%) | catalogued as COSV54299883; called by muse, mutect2, varscan2
- TGFBR2 | c.829A>G p.K277E | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55444129; called by muse, mutect2, varscan2
- TGM1 | c.1765G>T p.V589L | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.348); catalogued as COSV52861913; called by muse, mutect2, varscan2
- THADA | c.4161G>C p.L1387F | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV57676463; called by muse, mutect2, varscan2
- TMCC1 | c.1251T>A p.Y417* (on ENST00000393238 / NM_001349268.2; = p.Y93* on NM_015008.5 and 6 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 9/46 reads (20%) | catalogued as COSV61438724; called by muse, mutect2, varscan2
- TMEM108 | c.403G>C p.G135R | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV58864834, COSV58873831; called by muse, mutect2, varscan2
- TMEM139 | c.28C>A p.L10M | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV60081454; called by muse, mutect2, varscan2
- TMEM266 | c.211G>C p.D71H | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.81); catalogued as COSV66378618; called by muse, mutect2, varscan2
- TMEM43 | c.497G>T p.G166V | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs767516734, COSV60145326; called by muse, mutect2, varscan2
- TMPRSS11E | c.758C>A p.P253H | Missense Mutation (SNP) | VAF 44/209 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV59518017; called by muse, mutect2, varscan2
- TNFRSF11A | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 34/217 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs537966416, COSV54021966; called by muse, mutect2, varscan2
- TNNI2 | c.89T>A p.L30Q | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53288760; called by muse, mutect2, varscan2
- TNR | c.259G>T p.A87S | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.026); catalogued as COSV99688035; called by muse, mutect2, varscan2
- TPO | c.2674C>T p.P892S | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as COSV61095558; called by muse, mutect2, varscan2
- TPR | c.1031A>T p.E344V | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV66599542; called by muse, mutect2, varscan2
- TRAF3IP3 | c.916C>A p.R306= | Splice Region (SNP) | VAF 8/52 reads (15%) | catalogued as rs113331659, COSV50550574; called by muse, mutect2, varscan2
- TRIM10 | c.1014G>T p.W338C | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as COSV64998179; called by muse, mutect2, varscan2
- TRIM42 | c.108C>A p.N36K | Missense Mutation (SNP) | VAF 47/163 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as rs377609285; called by muse, mutect2, varscan2
- TRIM58 | c.748-2A>T p.X250_splice | Splice Site (SNP) | VAF 7/39 reads (18%) | catalogued as COSV100825165, COSV63569157; called by muse, mutect2, varscan2
- TRIM6 | c.743T>A p.L248Q | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV53474689; called by muse, mutect2
- TRIML2 | c.621G>T p.K207N | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.358); catalogued as COSV58714688; called by muse, mutect2, varscan2
- TRO | c.3984C>A p.D1328E | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.791); catalogued as COSV51497801; called by muse, mutect2, varscan2
- TRPV5 | c.91C>A p.Q31K | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as rs780603070, COSV54683238; called by muse, mutect2, varscan2
- TSHR | c.551T>A p.L184Q | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53314496; called by muse, mutect2, varscan2
- TSKU | c.819G>T p.E273D | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.078); catalogued as COSV60750862; called by muse, mutect2, varscan2
- TSPAN14 | c.466G>T p.A156S | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.134); catalogued as rs901787580, COSV55419827; called by muse, mutect2
- TTC8 | c.965A>G p.N322S (on ENST00000338104 / NM_001288781.1; = p.N306S on NM_144596.4) | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.086); catalogued as COSV57626315; called by muse, mutect2, varscan2
- UBE2C | c.387G>T p.R129S | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.604); catalogued as COSV54754456, COSV54755647; called by muse, mutect2, varscan2
- UBE2O | c.2819C>T p.S940F | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.451); catalogued as COSV60060410, COSV60062946; called by muse, mutect2, varscan2
- UBR4 | c.9463G>T p.A3155S | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.956); catalogued as COSV64383165; called by muse, varscan2
- UBR5 | c.4210A>T p.T1404S | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV55280579; called by muse, mutect2, varscan2
- UGT2A1 | c.152C>T p.T51I | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV54138331, COSV54143302; called by muse, mutect2, varscan2
- USH2A | c.13912C>A p.P4638T | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV56330696; called by muse, mutect2, varscan2
- USP31 | c.3865G>T p.G1289* | Nonsense Mutation (SNP) | VAF 59/279 reads (21%) | catalogued as COSV54849511, COSV54857119; called by muse, mutect2, varscan2
- USP6 | c.1013T>A p.V338E | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.804); catalogued as COSV51474883; called by muse, mutect2, varscan2
- USP9X | c.1705G>C p.A569P | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61066284; called by muse, mutect2, varscan2
- VARS2 | c.1316G>T p.R439L | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58911331; called by muse, mutect2, varscan2
- WIF1 | c.439G>T p.V147L | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV54129743; called by muse, mutect2, varscan2
- WNK1 | c.242G>C p.R81P | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV60026051; called by muse, mutect2, varscan2
- WSCD2 | c.1330C>A p.H444N | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0.091); catalogued as COSV54578364, COSV99775407; called by muse, mutect2, varscan2
- XIRP2 | c.3215C>A p.P1072Q (on ENST00000628543; = p.P1247Q on NM_152381.6) | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs957979251, COSV54683860; called by muse, mutect2, varscan2
- ZAN | c.1073T>C p.V358A | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV61805328; called by muse, mutect2, varscan2
- ZBTB24 | c.2081A>T p.Q694L | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV57781327; called by muse, mutect2, varscan2
- ZC3H4 | c.2002G>T p.G668C | Missense Mutation (SNP) | VAF 21/32 reads (66%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.97); catalogued as COSV53410706; called by muse, mutect2, varscan2
- ZDBF2 | c.1183C>T p.Q395* | Nonsense Mutation (SNP) | VAF 8/41 reads (20%) | catalogued as COSV65622086; called by muse, mutect2, varscan2
- ZFHX4 | c.7549C>T p.L2517F | Missense Mutation (SNP) | VAF 36/159 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV50507826; called by muse, mutect2, varscan2
- ZKSCAN3 | c.756G>T p.L252= | Splice Region (SNP) | VAF 4/48 reads (8%) | catalogued as COSV99356793; called by muse, mutect2
- ZNF121 | c.385A>T p.T129S | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.07); catalogued as COSV57551108; called by muse, mutect2, varscan2
- ZNF33A | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs763215496, COSV56723185; called by muse, mutect2, varscan2
- ZNF423 | c.2295G>T p.W765C (on ENST00000563137 / NM_001379286.1; = p.W757C on NM_015069.4) | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.967); catalogued as COSV52178231; called by muse, mutect2, varscan2
- ZNF423 | c.1961G>T p.S654I (on ENST00000563137 / NM_001379286.1; = p.S646I on NM_015069.4) | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.522); catalogued as COSV52178250; called by muse, mutect2, varscan2
- ZNF430 | c.1710G>A p.M570I | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as COSV55108114; called by muse, mutect2, varscan2
- ZNF438 | c.1172A>G p.D391G | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as rs748662387, COSV59192452; called by muse, mutect2, varscan2
- ZNF536 | c.3052C>G p.L1018V | Missense Mutation (SNP) | VAF 59/81 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as rs745641444, COSV62818950, COSV62834117; called by muse, mutect2, varscan2
- ZNF543 | c.1639G>C p.G547R | Missense Mutation (SNP) | VAF 40/81 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs755696317, COSV58626424, COSV58626537; called by muse, mutect2, varscan2
- ZNF569 | c.403A>C p.N135H | Missense Mutation (SNP) | VAF 65/115 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.161); catalogued as COSV57593720; called by muse, mutect2, varscan2
- ZNF611 | c.1727G>T p.S576I | Missense Mutation (SNP) | VAF 225/351 reads (64%) | SIFT tolerated (0.28); PolyPhen benign (0.043); catalogued as COSV100160535, COSV60539578; called by muse, mutect2, varscan2
- ZNF667 | c.484C>T p.H162Y | Missense Mutation (SNP) | VAF 105/161 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52631348; called by muse, mutect2, varscan2
- ZNF711 | c.524C>A p.A175E | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.834); catalogued as COSV52151595; called by muse, mutect2, varscan2
- ZNF74 | c.1199A>G p.H400R | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.76); PolyPhen benign (0.031); catalogued as COSV62620162; called by muse, mutect2, varscan2
- ZNF98 | c.1510C>A p.H504N | Missense Mutation (SNP) | VAF 98/144 reads (68%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as COSV63334597; called by muse, mutect2, varscan2
- ZNRF4 | c.767G>C p.W256S | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV55772989; called by muse, mutect2, varscan2
- ZZZ3 | c.29C>G p.T10R | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as COSV66231303; called by muse, mutect2, varscan2
- BHMT2 | c.136_141del p.P46_E47del | In Frame Del (DEL) | VAF 13/61 reads (21%) | called by mutect2, pindel, varscan2
- CDKAL1 | c.1100del p.P367Lfs*12 | Frame Shift Del (DEL) | VAF 15/51 reads (29%) | called by mutect2, pindel, varscan2
- CREBBP | c.2446del p.Q816Kfs*33 | Frame Shift Del (DEL) | VAF 14/47 reads (30%) | called by mutect2, pindel*, varscan2
- CTNND2 | c.1916C>A p.P639Q | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DISP2 | c.1623del p.F542Sfs*10 | Frame Shift Del (DEL) | VAF 13/38 reads (34%) | called by mutect2, pindel, varscan2
- EME2 | c.172_176del p.R58Gfs*73 | Frame Shift Del (DEL) | VAF 10/18 reads (56%) | called by mutect2, varscan2
- F9 | c.571del p.R191Vfs*12 | Frame Shift Del (DEL) | VAF 26/61 reads (43%) | called by mutect2, pindel, varscan2
- FRG2 | c.522C>A p.S174R | Missense Mutation (SNP) | VAF 49/169 reads (29%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- FRMPD2 | c.540dup p.G181Wfs*9 | Frame Shift Ins (INS) | VAF 26/92 reads (28%) | called by mutect2, pindel, varscan2
- GLCCI1 | c.1045_1046insCC p.Q349Pfs*79 | Frame Shift Ins (INS) | VAF 36/134 reads (27%) | called by pindel, varscan2
- GPR179 | c.415G>T p.E139* | Nonsense Mutation (SNP) | VAF 12/79 reads (15%) | called by muse, mutect2, varscan2
- IGKV2D-29 | c.6G>T p.R2S | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- LTBP2 | c.4171del p.A1391Lfs*100 | Frame Shift Del (DEL) | VAF 19/78 reads (24%) | called by mutect2, pindel, varscan2
- MYH15 | c.3194del p.H1065Pfs*7 | Frame Shift Del (DEL) | VAF 29/178 reads (16%) | called by mutect2, pindel, varscan2
- NCAPD3 | c.1870del p.V624Wfs*5 | Frame Shift Del (DEL) | VAF 26/90 reads (29%) | called by mutect2, pindel, varscan2
- OTOL1 | c.1165G>T p.V389F | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); called by mutect2, varscan2
- PRAMEF19 | c.310G>C p.E104Q | Missense Mutation (SNP) | VAF 39/596 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.162); called by muse, mutect2
- RBM15B | c.811G>A p.A271T | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2
- RET | c.97dup p.R33Kfs*29 | Frame Shift Ins (INS) | VAF 17/66 reads (26%) | called by mutect2, pindel, varscan2
- SERPINA9 | c.30dup p.A11Cfs*147 | Frame Shift Ins (INS) | VAF 8/63 reads (13%) | called by mutect2, pindel
- SLC9C1 | c.109del p.E37Kfs*9 | Frame Shift Del (DEL) | VAF 7/44 reads (16%) | called by mutect2, pindel, varscan2
- SPAG9 | c.3807_3814del p.M1269Ifs*14 (on ENST00000262013 / NM_001130528.3; = p.M1255Ifs*14 on NM_003971.6) | Frame Shift Del (DEL) | VAF 15/59 reads (25%) | called by mutect2, pindel*, varscan2*
- TBC1D3F | c.1487G>C p.*496Sext*16 | Nonstop Mutation (SNP) | VAF 49/226 reads (22%) | called by muse, mutect2, varscan2
- TPTE | c.1012T>A p.C338S (on ENST00000618007 / NM_199261.4; = p.C320S on NM_199259.4) | Missense Mutation (SNP) | VAF 39/218 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USP54 | c.3875_3901del p.T1292_H1301delinsN | In Frame Del (DEL) | VAF 6/68 reads (9%) | called by mutect2, pindel
- ZFHX4 | c.3770dup p.N1257Kfs*31 | Frame Shift Ins (INS) | VAF 16/63 reads (25%) | called by mutect2, pindel, varscan2
- ABCG4 | c.1611G>A p.V537= | Silent (SNP) | VAF 87/245 reads (36%) | catalogued as rs756388238, COSV56642121; called by muse, mutect2, varscan2
- AC127029.3 | c.672C>T p.A224= | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as COSV60110295; called by muse, mutect2, varscan2
- ACAN | c.6147T>C p.T2049= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs373971849; called by muse, mutect2, varscan2
- ACOT7 | c.1002G>A p.S334= (on ENST00000377855 / NM_181864.3; = p.S324= on NM_007274.4) | Silent (SNP) | VAF 3/28 reads (11%) | catalogued as rs1452901260, COSV64111883; called by muse, mutect2
- ACSM5 | c.1692T>A p.S564= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as COSV59369657; called by muse, mutect2, varscan2
- ADGRG1 | c.1851G>T p.L617= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as COSV65635218; called by muse, mutect2, varscan2
- ALDH1L1 | c.2682G>T p.R894= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV56410931; called by muse, mutect2
- ASIC3 | c.378G>T p.L126= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV52502396; called by muse, mutect2, varscan2
- ATAD5 | c.3291A>C p.G1097= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as COSV58972174; called by muse, mutect2
- ATF3 | c.183G>A p.A61= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs774446012, COSV100422134, COSV58377184; called by muse, mutect2, varscan2
- ATG4A | c.498C>T p.S166= | Silent (SNP) | VAF 22/56 reads (39%) | catalogued as COSV58964338; called by muse, mutect2, varscan2
- ATP1B2 | c.156C>G p.T52= | Silent (SNP) | VAF 36/105 reads (34%) | catalogued as COSV51514835; called by muse, mutect2, varscan2
- AUTS2 | c.3276G>A p.R1092= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as COSV61384622; called by muse, mutect2, varscan2
- BLK | c.1401C>G p.G467= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV52049611; called by muse, mutect2, varscan2
- BNC1 | c.168T>C p.C56= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as COSV61756574; called by muse, mutect2, varscan2
- BTN2A1 | c.1134G>T p.R378= | Silent (SNP) | VAF 21/78 reads (27%) | catalogued as COSV57002155; called by muse, mutect2, varscan2
- CABS1 | c.501G>A p.K167= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV56732988; called by muse, mutect2, varscan2
- CACNA1E | c.4371C>A p.T1457= | Silent (SNP) | VAF 6/72 reads (8%) | catalogued as COSV62383161; called by muse, mutect2
- CAPSL | c.253C>A p.R85= | Silent (SNP) | VAF 10/114 reads (9%) | catalogued as COSV101274195; called by muse, mutect2
- CCDC80 | c.1650G>A p.K550= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs1455339621, COSV52814892; called by muse, varscan2
- CCDC97 | c.660C>T p.L220= | Silent (SNP) | VAF 46/69 reads (67%) | catalogued as rs1325194465, COSV54189567; called by muse, mutect2, varscan2
- CCL17 | c.91C>A p.R31= | Silent (SNP) | VAF 41/123 reads (33%) | catalogued as COSV54664544; called by muse, mutect2, varscan2
- CDC45 | c.1419G>C p.L473= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV54243569; called by muse, mutect2, varscan2
- CDH2 | c.825A>T p.T275= | Silent (SNP) | VAF 59/158 reads (37%) | catalogued as COSV52272478; called by muse, mutect2, varscan2
- CHD6 | c.2583G>T p.A861= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV58554089, COSV58554707; called by muse, mutect2, varscan2
- CLCNKA | c.1626C>A p.S542= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV58890467, COSV58890978; called by muse, mutect2, varscan2
- CLEC16A | c.1872G>A p.K624= | Silent (SNP) | VAF 28/123 reads (23%) | catalogued as COSV68498030; called by muse, mutect2, varscan2
- CLIC5 | c.690C>T p.H230= (on ENST00000185206 / NM_001370649.1; = p.H71= on NM_016929.5) | Silent (SNP) | VAF 25/105 reads (24%) | catalogued as COSV51755423; called by muse, mutect2, varscan2
- CNTN2 | c.2346G>T p.T782= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as COSV59348277; called by muse, mutect2, varscan2
- CNTNAP2 | c.3186C>T p.C1062= | Silent (SNP) | VAF 17/86 reads (20%) | catalogued as COSV62147859; called by muse, mutect2, varscan2
- COL19A1 | c.1917G>A p.E639= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV59565865; called by muse, mutect2, varscan2
- COL1A2 | c.4044C>T p.D1348= | Silent (SNP) | VAF 26/166 reads (16%) | catalogued as rs1312827671, COSV51953256; called by muse, mutect2, varscan2
- CR1 | c.2751C>G p.T917= | Silent (SNP) | VAF 14/104 reads (13%) | catalogued as COSV65456049; called by muse, mutect2, varscan2
- CYP46A1 | c.594G>A p.G198= | Silent (SNP) | VAF 15/94 reads (16%) | catalogued as rs1334529993, COSV55893114; called by muse, mutect2, varscan2
- DCAF12L1 | c.1062G>A p.R354= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as rs138224583, COSV64421207; called by muse, mutect2, varscan2
- DGKI | c.2994A>C p.A998= | Silent (SNP) | VAF 3/34 reads (9%) | catalogued as COSV55937394; called by muse, mutect2
- DISP1 | c.3663C>T p.N1221= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as COSV52654984; called by muse, mutect2, varscan2
- DLG4 | c.1548A>T p.R516= (on ENST00000399506 / NM_001321075.3; = p.R559= on NM_001365.4) | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV57236772; called by muse, mutect2
- DMBT1 | c.2514G>A p.R838= | Silent (SNP) | VAF 40/213 reads (19%) | catalogued as rs1461470325, COSV57535165; called by muse, mutect2, varscan2
- DPYS | c.1266T>G p.A422= | Silent (SNP) | VAF 15/90 reads (17%) | catalogued as COSV60906534; called by muse, mutect2, varscan2
- DZIP1 | c.837G>A p.E279= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV61264097; called by muse, mutect2
- EDARADD | c.324G>T p.R108= (on ENST00000334232 / NM_145861.4; = p.R98= on NM_080738.4) | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV62061202; called by muse, mutect2, varscan2
- EGFL8 | c.234C>T p.Y78= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV61247068; called by muse, mutect2, varscan2
- ELP2 | c.672A>T p.L224= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV60848925; called by muse, mutect2, varscan2
- EPB41L4B | c.447G>A p.Q149= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as COSV65795629; called by muse, mutect2
- EPHA5 | c.801G>T p.V267= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV56632343; called by muse, mutect2, varscan2
- EXOG | c.84T>A p.A28= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as rs1354624903, COSV55062656; called by muse, mutect2, varscan2
- EXT2 | c.900C>T p.C300= (on ENST00000343631; = p.C333= on NM_000401.3) | Silent (SNP) | VAF 16/87 reads (18%) | catalogued as COSV59147056; called by muse, mutect2, varscan2
- FABP6 | c.285C>T p.F95= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV67436708; called by muse, mutect2, varscan2
- FAM71E1 | c.450G>T p.G150= (on ENST00000600100 / NM_001308429.2; = p.G134= on NM_138411.3) | Silent (SNP) | VAF 11/21 reads (52%) | catalogued as COSV100618415; called by muse, mutect2, varscan2
- FEV | c.432C>T p.A144= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV99837862; called by muse, mutect2, varscan2
- FHL5 | c.756C>T p.C252= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as rs201145903, COSV58735884; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1566A>G p.Q522= | Silent (SNP) | VAF 19/105 reads (18%) | catalogued as COSV58546298; called by muse, mutect2, varscan2
- FRG1 | c.729G>T p.T243= | Silent (SNP) | VAF 25/101 reads (25%) | catalogued as COSV56996307; called by muse, mutect2, varscan2
- FSHR | c.2010C>T p.G670= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as COSV100437454, COSV58617985; called by muse, mutect2, varscan2
- GJB5 | c.495C>T p.H165= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as rs149592496; called by muse, mutect2, varscan2
- GLI3 | c.3186G>A p.S1062= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as rs747635516, COSV67885475; called by muse, mutect2, varscan2
- GNAQ | c.231G>A p.K77= | Silent (SNP) | VAF 40/128 reads (31%) | catalogued as COSV54107517; called by muse, mutect2, varscan2
- GPR132 | c.285G>T p.L95= | Silent (SNP) | VAF 28/158 reads (18%) | catalogued as COSV61677592; called by muse, mutect2, varscan2
- GPR156 | c.2280G>T p.R760= | Silent (SNP) | VAF 42/150 reads (28%) | catalogued as COSV100251861, COSV59938170; called by muse, mutect2, varscan2
- GREM1 | c.87C>T p.S29= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as COSV55714411; called by muse, mutect2, varscan2
- GRIK2 | c.477C>A p.A159= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as COSV59713594; called by muse, mutect2, varscan2
- GRXCR1 | c.339G>T p.V113= | Silent (SNP) | VAF 9/87 reads (10%) | catalogued as COSV67670196; called by muse, mutect2, varscan2
- HAS1 | c.1323G>T p.V441= | Silent (SNP) | VAF 24/37 reads (65%) | catalogued as COSV55786226; called by muse, mutect2, varscan2
- IGHV1-18 | c.249C>G p.L83= | Silent (SNP) | VAF 34/203 reads (17%) | catalogued as rs782171300; called by muse, mutect2, varscan2
- IGKV1-27 | c.118A>C p.R40= | Silent (SNP) | VAF 25/101 reads (25%) | called by muse, mutect2, varscan2
- KCNQ3 | c.1344G>T p.L448= | Silent (SNP) | VAF 32/136 reads (24%) | catalogued as COSV66464168; called by muse, mutect2, varscan2
- KRT2 | c.729C>G p.L243= | Silent (SNP) | VAF 43/125 reads (34%) | catalogued as COSV59009116, COSV59009136; called by muse, mutect2, varscan2
- KRT5 | c.87C>T p.R29= | Silent (SNP) | VAF 21/41 reads (51%) | catalogued as COSV52859021, COSV52862059; called by muse, mutect2, varscan2
- KRTAP12-3 | c.159C>A p.S53= | Silent (SNP) | VAF 25/78 reads (32%) | catalogued as rs782775669, COSV100553463, COSV59952853; called by muse, mutect2, varscan2
- KRTAP27-1 | c.555C>A p.L185= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as COSV67000865, COSV67000893; called by muse, mutect2, varscan2
- LAMC3 | c.4308G>T p.T1436= | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as rs201023030, COSV62653336, COSV62654941, COSV62655551; called by muse, mutect2
- LMX1A | c.216C>T p.T72= | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as COSV54217156; called by muse, mutect2, varscan2
- LNX1 | c.1752G>C p.S584= (on ENST00000263925 / NM_001126328.3; = p.S488= on NM_032622.2) | Silent (SNP) | VAF 23/111 reads (21%) | catalogued as rs752968070, COSV55782234, COSV99819947; called by muse, mutect2, varscan2
- LRBA | c.3774G>A p.L1258= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV63950251; called by muse, mutect2, varscan2
- LRIF1 | c.1116A>T p.T372= | Silent (SNP) | VAF 24/179 reads (13%) | catalogued as COSV63896665; called by muse, mutect2, varscan2
- LRP2 | c.13584C>T p.A4528= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as COSV55541752; called by muse, mutect2, varscan2
- LRP2 | c.2223T>C p.S741= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV55541760; called by muse, mutect2, varscan2
- LRRC74A | c.1170G>A p.L390= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as rs757847846, COSV53607976; called by muse, mutect2, varscan2
- LTB | c.624C>G p.G208= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV71333626, COSV71333656; called by muse, mutect2, varscan2
- MAGEA11 | c.1251G>A p.L417= | Silent (SNP) | VAF 44/69 reads (64%) | catalogued as COSV60753792; called by muse, mutect2, varscan2
- MAP2K3 | c.501G>A p.G167= (on ENST00000342679 / NM_145109.3; = p.G138= on NM_002756.4) | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV57562258; called by muse, mutect2, varscan2
- MBL2 | c.420G>T p.L140= | Silent (SNP) | VAF 12/115 reads (10%) | called by muse, mutect2
- MCHR1 | c.1182G>T p.S394= | Silent (SNP) | VAF 35/90 reads (39%) | catalogued as COSV50760363; called by muse, mutect2, varscan2
- MECOM | c.2037T>C p.T679= (on ENST00000468789 / NM_001105078.4; = p.T867= on NM_004991.4) | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV52960052; called by muse, mutect2, varscan2
- MED12L | c.150C>A p.A50= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV56369247; called by muse, mutect2, varscan2
- MINDY4 | c.1062C>T p.P354= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as rs536189237, COSV54671356; called by muse, mutect2
- MRAP2 | c.192G>T p.L64= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as COSV57631493; called by muse, mutect2, varscan2
- MYH11 | c.4533C>A p.A1511= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as COSV100257908; called by muse, mutect2, varscan2
- MYH4 | c.4041G>A p.L1347= | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as COSV55112653; called by muse, mutect2, varscan2
- MYLK3 | c.2457C>A p.P819= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as rs1302194045, COSV67362638; called by muse, mutect2, varscan2
- MYO10 | c.1026C>T p.I342= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as rs745750225, COSV72562879; called by muse, mutect2, varscan2
- MYRIP | c.1632C>T p.P544= | Silent (SNP) | VAF 3/41 reads (7%) | catalogued as COSV56862505; called by muse, mutect2
- NAA11 | c.204G>T p.P68= | Silent (SNP) | VAF 12/98 reads (12%) | catalogued as COSV54513872, COSV54513940; called by muse, mutect2
- NAV3 | c.3420C>G p.R1140= | Silent (SNP) | VAF 20/49 reads (41%) | catalogued as COSV57063283; called by muse, mutect2, varscan2
- NAV3 | c.3873G>T p.P1291= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV57063293, COSV57081954; called by muse, mutect2, varscan2
- NCOR2 | c.639C>G p.P213= | Silent (SNP) | VAF 22/76 reads (29%) | catalogued as COSV62293543; called by muse, varscan2
- NKAPL | c.144T>C p.R48= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as COSV59197011, COSV59198719; called by muse, mutect2, varscan2
- NLRC3 | c.1272T>A p.G424= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV57087477; called by muse, mutect2
- NPAP1 | c.109C>A p.R37= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV61504665; called by muse, mutect2, varscan2
- OPRPN | c.267A>T p.P89= | Silent (SNP) | VAF 30/230 reads (13%) | catalogued as COSV101271095, COSV68192600; called by muse, mutect2, varscan2
- OPTC | c.978C>A p.L326= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV65867285; called by muse, mutect2, varscan2
- OR52K2 | c.102C>T p.C34= | Silent (SNP) | VAF 32/108 reads (30%) | catalogued as COSV57834624; called by muse, mutect2, varscan2
- OR6A2 | c.513C>A p.L171= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as COSV60264456; called by muse, mutect2, varscan2
- OR6C76 | c.312T>C p.L104= | Silent (SNP) | VAF 24/196 reads (12%) | catalogued as rs986385529, COSV60388627; called by muse, mutect2, varscan2
- P2RX4 | c.648G>A p.S216= | Silent (SNP) | VAF 34/97 reads (35%) | catalogued as rs372212344; called by muse, mutect2, varscan2
- PADI3 | c.777C>A p.A259= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV100968411, COSV64934907; called by muse, mutect2
- PCDHB7 | c.2172G>T p.S724= | Silent (SNP) | VAF 44/106 reads (42%) | catalogued as COSV50754616, COSV99176006; called by muse, mutect2, varscan2
- PGBD2 | c.921G>T p.V307= | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as COSV61399628; called by muse, mutect2, varscan2
- PGF | c.288G>T p.P96= | Silent (SNP) | VAF 11/75 reads (15%) | catalogued as rs371574652, COSV99462279; called by muse, mutect2, varscan2
- PIK3CA | c.627G>A p.L209= | Silent (SNP) | VAF 45/125 reads (36%) | catalogued as COSV55883870; called by muse, mutect2, varscan2
- PKD1 | c.3747C>T p.D1249= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as rs148021876; called by muse, mutect2, varscan2
- PSME2 | c.564G>A p.R188= | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as COSV52823364; called by muse, mutect2
- PTDSS1 | c.837C>T p.D279= | Silent (SNP) | VAF 37/203 reads (18%) | catalogued as COSV61263682; called by muse, mutect2, varscan2
- PTGDR | c.729T>C p.C243= | Silent (SNP) | VAF 31/90 reads (34%) | catalogued as COSV60093127; called by muse, mutect2, varscan2
- PXDN | c.789G>T p.V263= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV53227448; called by muse, mutect2
- PXDNL | c.3015G>T p.V1005= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV62479055; called by muse, mutect2
- RASAL3 | c.207G>T p.R69= | Silent (SNP) | VAF 25/36 reads (69%) | catalogued as COSV52991424; called by muse, mutect2, varscan2
- RBFOX1 | c.264C>G p.T88= | Silent (SNP) | VAF 23/108 reads (21%) | catalogued as COSV60946759; called by muse, mutect2, varscan2
- RGS9 | c.669T>C p.V223= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as rs1201163958, COSV52223214; called by muse, mutect2, varscan2
- RPS10-NUDT3 | c.438A>T p.S146= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV58241705; called by muse, mutect2, varscan2
- SALL3 | c.2406G>A p.E802= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV73305781; called by muse, mutect2
- SCLT1 | c.1959G>A p.R653= | Silent (SNP) | VAF 6/98 reads (6%) | catalogued as COSV55401836; called by muse, mutect2
- SCN4A | c.531G>T p.L177= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV71125675; called by muse, mutect2, varscan2
- SDC4 | c.18G>T p.L6= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV101023374; called by muse, mutect2
- SEC14L5 | c.798C>T p.H266= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV52036493; called by muse, mutect2
- SIM1 | c.2199C>A p.G733= | Silent (SNP) | VAF 14/110 reads (13%) | catalogued as COSV53489174, COSV99492422; called by muse, mutect2, varscan2
- SLC12A5 | c.657C>A p.I219= (on ENST00000454036 / NM_001134771.2; = p.I196= on NM_020708.5) | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV54788893; called by muse, mutect2, varscan2
- SLC35G3 | c.549G>T p.G183= | Silent (SNP) | VAF 26/124 reads (21%) | catalogued as COSV52010316, COSV52012901; called by muse, mutect2, varscan2
- SLC38A8 | c.48C>T p.H16= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as COSV55304844; called by muse, mutect2
- SLC6A3 | c.702G>C p.G234= | Silent (SNP) | VAF 79/154 reads (51%) | catalogued as COSV54361770; called by muse, mutect2, varscan2
- SLC7A13 | c.1281G>C p.L427= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV52532583; called by muse, mutect2, varscan2
- SNAPIN | c.39G>T p.G13= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV62626976; called by muse, mutect2, varscan2
- SORBS2 | c.3165G>A p.R1055= (on ENST00000284776 / NM_021069.5; = p.R621= on NM_003603.6) | Silent (SNP) | VAF 28/104 reads (27%) | catalogued as COSV52991767; called by muse, mutect2, varscan2
- SRSF4 | c.1224C>T p.S408= | Silent (SNP) | VAF 51/187 reads (27%) | catalogued as COSV65694105; called by muse, mutect2, varscan2
- STYXL2 | c.3096C>A p.S1032= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV54802219; called by muse, mutect2, varscan2
- SZT2 | c.5052G>T p.T1684= (on ENST00000634258 / NM_001365999.1; = p.T1627= on NM_015284.4) | Silent (SNP) | VAF 13/133 reads (10%) | catalogued as COSV65167325, COSV65171810; called by muse, mutect2, varscan2
- TAS2R5 | c.873G>T p.V291= | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as COSV56094432; called by muse, mutect2, varscan2
- TBC1D10C | c.111C>A p.A37= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as rs367558435, COSV100408144; called by muse, mutect2, varscan2
- TBX18 | c.1773C>A p.T591= | Silent (SNP) | VAF 5/55 reads (9%) | catalogued as COSV63736119; called by muse, mutect2, varscan2
- TBX18 | c.870G>T p.G290= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV63736122; called by muse, mutect2, varscan2
- TCTE1 | c.363C>A p.T121= | Silent (SNP) | VAF 30/128 reads (23%) | catalogued as COSV101025332; called by muse, mutect2, varscan2
- TF | c.1191C>A p.I397= | Silent (SNP) | VAF 21/64 reads (33%) | catalogued as COSV53917959, COSV53918224; called by muse, mutect2, varscan2
- THAP10 | c.36C>T p.N12= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as COSV51436205; called by muse, mutect2
- THOP1 | c.558G>C p.T186= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV57017747; called by muse, mutect2
- TMEM53 | c.825C>T p.V275= | Silent (SNP) | VAF 5/75 reads (7%) | catalogued as COSV59189836; called by muse, mutect2
- TOX3 | c.777G>T p.V259= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as COSV54863002; called by muse, mutect2, varscan2
- TP53BP2 | c.1194C>T p.N398= (on ENST00000343537 / NM_001031685.3; = p.N269= on NM_005426.2) | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as COSV59066535, COSV59068241; called by muse, mutect2, varscan2
- TPCN2 | c.907C>T p.L303= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV53727265; called by muse, mutect2
- TREM1 | c.78G>A p.E26= | Silent (SNP) | VAF 36/134 reads (27%) | catalogued as COSV55147834; called by muse, mutect2, varscan2
- TTN | c.20778A>T p.P6926= (on ENST00000591111; = p.P5999= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV59899721; called by muse, mutect2, varscan2
- UHRF1BP1 | c.2442A>G p.A814= | Silent (SNP) | VAF 26/172 reads (15%) | catalogued as COSV51952916; called by muse, mutect2, varscan2
- USH2A | c.1953T>A p.G651= | Silent (SNP) | VAF 13/71 reads (18%) | catalogued as COSV56330715; called by muse, mutect2, varscan2
- UTRN | c.5020C>T p.L1674= | Silent (SNP) | VAF 21/66 reads (32%) | catalogued as COSV62328986; called by muse, mutect2, varscan2
- VNN2 | c.981C>A p.I327= | Silent (SNP) | VAF 19/96 reads (20%) | catalogued as COSV58471562, COSV58472073; called by muse, mutect2, varscan2
- VPS13C | c.5706T>A p.T1902= (on ENST00000644861 / NM_020821.3; = p.T1859= on NM_017684.5) | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV51123288; called by muse, mutect2, varscan2
- YTHDF1 | c.1365C>T p.P455= | Silent (SNP) | VAF 10/98 reads (10%) | catalogued as rs919727844, COSV64832518; called by muse, mutect2, varscan2
- ZNF763 | c.588G>T p.G196= (on ENST00000358987 / NM_001367172.2; = p.G199= on NM_001012753.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 68/136 reads (50%) | catalogued as COSV59687166; called by muse, mutect2, varscan2
- ZNF99 | c.78G>A p.Q26= | Silent (SNP) | VAF 86/130 reads (66%) | catalogued as COSV101233726, COSV68054830, COSV68055694; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73846081 T>A | 5'Flank (SNP) | VAF 26/51 reads (51%) | called by muse, mutect2, varscan2
- CABYR | c.*17-219A>G | Intron (SNP) | VAF 7/90 reads (8%) | catalogued as COSV100111250; called by muse, mutect2
- CAPZB | c.*20G>T | 3'UTR (SNP) | VAF 33/171 reads (19%) | catalogued as COSV51644516; called by muse, mutect2, varscan2
- CDH11 | c.1895-510G>A | Intron (SNP) | VAF 9/38 reads (24%) | catalogued as rs867291225, COSV99216907; called by muse, mutect2, varscan2
- DCHS2 | n.7791C>T | RNA (SNP) | VAF 17/100 reads (17%) | catalogued as COSV61768318; called by muse, mutect2, varscan2
- IGKV2OR22-4 | n.105C>G | RNA (SNP) | VAF 15/45 reads (33%) | called by muse, mutect2, varscan2
- KRT18P55 | n.1047T>A | RNA (SNP) | VAF 15/63 reads (24%) | called by muse, mutect2, varscan2
- LINC02843 | n.417G>T | RNA (SNP) | VAF 17/81 reads (21%) | called by muse, mutect2, varscan2
- MYB | c.1203+1252A>G | Intron (SNP) | VAF 7/37 reads (19%) | catalogued as COSV100214608; called by muse, mutect2, varscan2
- NXF5 | n.390G>T | RNA (SNP) | VAF 81/149 reads (54%) | catalogued as COSV53789559, COSV53789771; called by muse, mutect2, varscan2
- OBSCN | c.11659+4980A>G | Intron (SNP) | VAF 8/42 reads (19%) | catalogued as COSV99474000; called by muse, mutect2, varscan2
- OR4P4 | c.-2C>T | 5'UTR (SNP) | VAF 18/230 reads (8%) | catalogued as rs751805923, COSV100111588; called by muse, mutect2
- OTOF | c.*194C>A | 3'UTR (SNP) | VAF 10/54 reads (19%) | catalogued as COSV99716746; called by muse, mutect2, varscan2
- PSG5 | c.431-2799C>A | Intron (SNP) | VAF 180/342 reads (53%) | catalogued as COSV100742576, COSV100742824; called by muse, mutect2, varscan2
- QKI | c.934+951G>T | Intron (SNP) | VAF 7/60 reads (12%) | catalogued as COSV99274433; called by muse, mutect2, varscan2
- RPL23 | c.97+27C>A | Intron (SNP) | VAF 10/52 reads (19%) | catalogued as rs762165920, COSV99834653; called by muse, mutect2, varscan2
- STAU1 | c.610-11del | Intron (DEL) | VAF 12/53 reads (23%) | catalogued as COSV100574215; called by mutect2, pindel, varscan2
- TTN | c.10360+4659T>C | Intron (SNP) | VAF 14/170 reads (8%) | catalogued as rs1203856781, COSV59899731; called by muse, mutect2
- UMODL1 | c.1900-103C>A | Intron (SNP) | VAF 13/33 reads (39%) | catalogued as COSV100210588; called by muse, mutect2, varscan2
- ZC3H14 | c.1280-1905G>T | Intron (SNP) | VAF 16/77 reads (21%) | catalogued as COSV99192963, COSV99193020; called by muse, mutect2, varscan2
